Somatic mutation profile of tumor specimen TCGA-AA-3532-01A (aliquot TCGA-AA-3532-01A-01D-1953-10) from TCGA case TCGA-AA-3532, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.3 years (23,133 days).
Specimen TCGA-AA-3532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a71a49b8-6b6b-46f3-a875-d1ffa80d0363.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3532-11A (Solid Tissue Normal), aliquot TCGA-AA-3532-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8893e512-c277-4a16-b0e1-db586bb0edee

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, In Frame Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54856697; called by muse, mutect2, varscan2
- BSN | c.10664G>A p.R3555H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1475618613, COSV56527786; called by muse, mutect2, varscan2
- CATSPERD | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 62/467 reads (13%) | catalogued as COSV101062331; called by muse, mutect2, varscan2
- EIF2AK4 | c.209A>C p.Y70S | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99773988; called by muse, mutect2
- F7 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs147680958, CM001151; called by muse, mutect2, varscan2
- HRH3 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs201799413, COSV100420420; called by muse, mutect2
- KCNG1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100856970; called by muse, mutect2, varscan2
- MSH6 | c.38A>C p.K13T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs41294988, CM088568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- P2RX1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 110/302 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260154981, COSV99844507; called by muse, mutect2, varscan2
- PPP1R13B | c.3112C>A p.L1038M | Missense Mutation (SNP) | VAF 78/393 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99157471; called by muse, mutect2, varscan2
- PRRT3 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 69/366 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99926268; called by muse, mutect2, varscan2
- PTPN21 | c.1892A>G p.Q631R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as rs1296165843, COSV60850893; called by muse, mutect2, varscan2
- RIMS2 | c.2110_2111insG p.M704Sfs*35 (on ENST00000666250 / NM_001348490.2; = p.M512Sfs*35 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 96/930 reads (10%) | catalogued as COSV99156952, COSV99167366; called by mutect2, varscan2
- SLC11A1 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99261820; called by muse, mutect2, varscan2
- XPO4 | c.1772A>C p.K591T | Missense Mutation (SNP) | VAF 59/583 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as COSV99687922; called by muse, mutect2, varscan2
- ZNF831 | c.4694C>T p.T1565I | Missense Mutation (SNP) | VAF 170/391 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100925741; called by muse, mutect2, varscan2
- PCDHA5 | c.1472_1474del p.Y491del | In Frame Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- STX12 | c.40_45del p.P14_S15del | In Frame Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- AMPD2 | c.900A>G p.E300= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56647392, COSV56651417; called by muse, varscan2
- CFAP74 | c.882G>A p.A294= | Silent (SNP) | VAF 33/188 reads (18%) | catalogued as rs867517016, COSV54566038; called by muse, mutect2, varscan2
- TH | c.603G>A p.V201= (on ENST00000381178 / NM_199292.3; = p.V170= on NM_000360.4) | Silent (SNP) | VAF 62/459 reads (14%) | catalogued as COSV100147035; called by muse, mutect2, varscan2
